Somatic mutation profile of tumor specimen MMRF_1835_1_BM_CD138pos (aliquot MMRF_1835_1_BM_CD138pos_T1_KBS5U_L05538) from MMRF case MMRF_1835, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.5 years (24,304 days).
Specimen MMRF_1835_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a6ff8d2-c76f-405c-b2e1-8dcf00845d9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1835_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1835_1_PB_Whole_C3_KBS5U_L05539; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2c5541e-0cfb-4d05-afcb-5636b5b98276

The open-access MAF lists 135 somatic variants for this specimen: 47 protein-altering or splice-affecting, 18 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 32, Intron 20, Silent 18, 3'Flank 6, 5'Flank 5, RNA 4, 5'UTR 3, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 17/127 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 17/135 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- NRAS | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 164/508 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: likely pathogenic; called by muse, varscan2
- CYP2C19 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 17/364 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as rs1349931378, CM1510886, COSV64909909; called by muse, mutect2
- EFTUD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53655180; called by muse, mutect2, varscan2
- FGF14 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101085232; called by muse, mutect2, varscan2
- FNDC3B | c.3165dup p.T1056Hfs*16 | Frame Shift Ins (INS) | VAF 20/88 reads (23%) | catalogued as rs769012096; called by mutect2, varscan2
- IGHV1-69 | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs11557984; called by mutect2, varscan2
- INO80 | c.1267A>G p.T423A | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62741254; called by muse, mutect2
- KCND2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs756823168, COSV58586030; called by muse, mutect2
- KCNN1 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.418); catalogued as COSV55837064; called by muse, mutect2, varscan2
- NRXN2 | c.5020C>T p.R1674* | Nonsense Mutation (SNP) | VAF 65/181 reads (36%) | catalogued as COSV55454115, COSV99632666; called by muse, mutect2, varscan2
- PACRG | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1212278700, COSV61308713, COSV61315792; called by muse, mutect2
- PCDHA3 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV63540702; called by muse, mutect2, varscan2
- RPS15 | c.274_285del p.S92_G95del | In Frame Del (DEL) | VAF 27/69 reads (39%) | catalogued as rs1336285256; called by mutect2, varscan2
- RPS15 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV51833514; called by muse, mutect2, varscan2
- SARS1 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs558790737; called by muse, mutect2, varscan2
- SIX4 | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV53670176; called by muse, mutect2
- SOS2 | c.3158G>A p.R1053Q | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs898581242; called by muse, mutect2, varscan2
- STIL | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 15/301 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs1014673459; called by muse, mutect2
- ZFP91 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV60157005; called by muse, mutect2
- ZNF558 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256254386, COSV56864045; called by muse, mutect2
- CABS1 | c.458A>G p.D153G | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2
- CCNK | c.1351A>G p.M451V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHD2 | c.5010C>G p.Y1670* | Nonsense Mutation (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- CTTNBP2 | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DACT1 | c.1766_1775del p.P589Rfs*100 | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.7C>G p.P3A | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- FRYL | c.4882T>G p.F1628V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- GPR1 | c.502A>T p.I168F | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2
- HSPA12A | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KANSL1L | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- KMT2B | c.7406A>G p.H2469R | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- LINC02291 | n.625+4A>C | Splice Region (SNP) | VAF 35/117 reads (30%) | called by muse, mutect2
- LOXL1 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- LRRTM4 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 19/396 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2
- MBD2 | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, mutect2
- MCF2L2 | c.3154A>G p.K1052E | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.018); called by muse, mutect2
- MMP1 | c.277G>C p.G93R | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PEG10 | c.242A>G p.D81G (on ENST00000482108 / NM_001040152.2; = p.D115G on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- PKHD1L1 | c.2120C>T p.T707I | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.07); called by muse, mutect2
- PPEF1 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC15A4 | c.735C>G p.S245R | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.176); called by muse, mutect2
- TBL1Y | c.675A>G p.I225M | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- TRIM25 | c.1663A>T p.N555Y | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- UNC5C | c.1612T>G p.S538A | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF736 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 11/274 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- CHSY1 | c.1758G>T p.L586= | Silent (SNP) | VAF 15/183 reads (8%) | catalogued as COSV54252415; called by muse, mutect2
- DIAPH1 | c.6G>A p.E2= | Silent (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- ERN2 | c.714C>T p.D238= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs765296409; called by muse, mutect2, varscan2
- FSIP2 | c.5307C>G p.L1769= | Silent (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- FSIP2 | c.5880A>T p.T1960= | Silent (SNP) | VAF 57/166 reads (34%) | called by muse, mutect2, varscan2
- HEATR5B | c.5301C>A p.S1767= | Silent (SNP) | VAF 28/171 reads (16%) | catalogued as COSV51857401; called by muse, mutect2, varscan2
- IGHJ5 | c.15C>A p.P5= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs782527450; called by muse, varscan2
- IGLV5-45 | c.108A>G p.S36= | Silent (SNP) | VAF 109/249 reads (44%) | catalogued as rs371931023; called by muse, mutect2, varscan2
- INMT | c.606G>A p.P202= | Silent (SNP) | VAF 50/118 reads (42%) | catalogued as rs558249086, COSV50000369; called by muse, mutect2, varscan2
- IRF2BPL | c.351G>A p.Q117= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs765159340, COSV53146287; called by muse, varscan2
- KCNMA1 | c.153T>C p.S51= | Silent (SNP) | VAF 43/85 reads (51%) | catalogued as rs200164685, COSV54303763; called by muse, mutect2, varscan2
- KIR3DL3 | c.642C>T p.D214= | Silent (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- LATS1 | c.1692G>A p.L564= | Silent (SNP) | VAF 40/100 reads (40%) | called by muse, mutect2, varscan2
- LRRC53 | c.2148C>T p.N716= | Silent (SNP) | VAF 94/262 reads (36%) | called by muse, mutect2, varscan2
- NLRC5 | c.1791G>A p.Q597= | Silent (SNP) | VAF 59/150 reads (39%) | called by muse, mutect2, varscan2
- TAF10 | c.511C>T p.L171= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV100196159; called by muse, mutect2
- TBCE | c.288G>A p.E96= | Silent (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- TENM1 | c.7212C>T p.N2404= | Silent (SNP) | VAF 35/45 reads (78%) | called by mutect2, varscan2
- ABHD12B | c.*129T>C | 3'UTR (SNP) | VAF 50/135 reads (37%) | called by muse, mutect2, varscan2
- AC009053.1 | n.1871C>T | RNA (SNP) | VAF 32/190 reads (17%) | called by muse, mutect2, varscan2
- ADAM9 | c.*1138C>T | 3'UTR (SNP) | VAF 59/158 reads (37%) | catalogued as rs576534966; called by muse, mutect2, varscan2
- ADGB | c.752+50A>T | Intron (SNP) | VAF 8/204 reads (4%) | called by muse, mutect2
- ATP6AP1L | n.1870T>C | RNA (SNP) | VAF 18/50 reads (36%) | catalogued as COSV66474227; called by muse, mutect2, varscan2
- BANK1 | chr4:101790704 G>C | 5'Flank (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- BEND5 | c.-11C>T | 5'UTR (SNP) | VAF 3/40 reads (8%) | catalogued as rs1290904816; called by muse, mutect2
- CACNA1B | c.530+9313G>A | Intron (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- CACNA2D1 | chr7:81947730 T>G | 3'Flank (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- CALML5 | c.*28C>T | 3'UTR (SNP) | VAF 11/51 reads (22%) | catalogued as rs1025170461, COSV100981231; called by muse, mutect2, varscan2
- CARD14 | c.844-70C>T | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as rs1485544888; called by muse, mutect2, varscan2
- CCER1 | c.*446T>G | 3'UTR (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2, varscan2
- CCL22 | c.*1904_*1905dup | 3'UTR (INS) | VAF 57/92 reads (62%) | catalogued as rs376775833; called by mutect2, varscan2
- CD52 | c.*19T>C | 3'UTR (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- CIAO3 | c.306+76G>A | Intron (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- CRPPA | c.*425A>T | 3'UTR (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- CYP26C1 | c.705+127C>G | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- DNAJA4 | c.878-55G>A | Intron (SNP) | VAF 6/87 reads (7%) | catalogued as rs985927330; called by muse, mutect2
- EPHB4 | c.2484+109dup | Intron (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- ERBB4 | c.*2772G>T | 3'UTR (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- FAT4 | c.*124A>C | 3'UTR (SNP) | VAF 15/262 reads (6%) | called by muse, mutect2
- FPGT-TNNI3K | c.2114+3590A>G | Intron (SNP) | VAF 36/56 reads (64%) | called by muse, mutect2, varscan2
- HAND2 | c.-494C>A | 5'UTR (SNP) | VAF 12/145 reads (8%) | called by muse, mutect2
- HIP1 | c.*3877C>T | 3'UTR (SNP) | VAF 71/140 reads (51%) | catalogued as rs1222339992; called by muse, mutect2, varscan2
- HIVEP3 | c.*1570C>T | 3'UTR (SNP) | VAF 38/100 reads (38%) | catalogued as rs1417094429; called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863416 T>C | 5'Flank (SNP) | VAF 7/20 reads (35%) | called by muse, varscan2
- IL17D | c.*551A>G | 3'UTR (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- INKA2 | c.*4163T>G | 3'UTR (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- IP6K2 | c.202+54C>T | Intron (SNP) | VAF 74/192 reads (39%) | catalogued as rs1304312111; called by muse, mutect2, varscan2
- KDSR | c.*2580G>A | 3'UTR (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- KRT38 | c.-12C>T | 5'UTR (SNP) | VAF 4/8 reads (50%) | catalogued as rs201232784; called by muse, varscan2
- LGI2 | c.*1683G>A | 3'UTR (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- LPAR3 | c.*1871T>C | 3'UTR (SNP) | VAF 4/80 reads (5%) | catalogued as rs1192046796; called by muse, mutect2
- LTB | c.163-138C>G | Intron (SNP) | VAF 100/204 reads (49%) | called by muse, varscan2
- LZTS1 | c.*2008C>T | 3'UTR (SNP) | VAF 66/138 reads (48%) | catalogued as rs1196024662; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851126 T>A | 5'Flank (SNP) | VAF 112/243 reads (46%) | catalogued as rs569234583; called by muse, varscan2
- MIR5195 | chr14:106851175 T>A | 5'Flank (SNP) | VAF 88/198 reads (44%) | catalogued as rs529449665; called by muse, varscan2
- MLXIP | c.*2782A>C | 3'UTR (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- MSR1 | c.1034-552G>A | Intron (SNP) | VAF 87/266 reads (33%) | called by muse, mutect2, varscan2
- MSR1 | c.1034-553G>A | Intron (SNP) | VAF 86/265 reads (32%) | called by muse, mutect2, varscan2
- MYO9A | c.*676G>T | 3'UTR (SNP) | VAF 46/88 reads (52%) | catalogued as rs913986568; called by muse, mutect2, varscan2
- NOL9 | chr1:6519930 G>C | 3'Flank (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- NPFF | c.102+19C>T | Intron (SNP) | VAF 52/178 reads (29%) | catalogued as rs745512380; called by muse, mutect2, varscan2
- OR4C48P | n.495C>A | RNA (SNP) | VAF 49/136 reads (36%) | called by muse, mutect2, varscan2
- OTOGL | c.6735+92T>G | Intron (SNP) | VAF 52/96 reads (54%) | called by muse, mutect2, varscan2
- PAQR6 | c.*794G>C | 3'UTR (SNP) | VAF 34/59 reads (58%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-13939A>G | Intron (SNP) | VAF 7/148 reads (5%) | called by muse, mutect2
- POU2F3 | c.*982A>G | 3'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- PRKAR1B | chr7:549530 G>A | 3'Flank (SNP) | VAF 12/335 reads (4%) | catalogued as rs1485789700; called by muse, mutect2
- PRTG | c.*7819A>T | 3'UTR (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- RAB14 | c.*346T>G | 3'UTR (SNP) | VAF 37/94 reads (39%) | catalogued as rs1276266649; called by muse, mutect2, varscan2
- RAPGEF5 | c.1099-11T>C | Intron (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- RASEF | c.*60T>C | 3'UTR (SNP) | VAF 206/393 reads (52%) | called by muse, mutect2, varscan2
- RASSF8 | chr12:26069063 T>G | 3'Flank (SNP) | VAF 36/95 reads (38%) | called by muse, mutect2, varscan2
- RPS2 | c.268-458_268-457insC | Intron (INS) | VAF 7/18 reads (39%) | called by mutect2, pindel*
- SERPINA3 | c.644-888T>C | Intron (SNP) | VAF 31/102 reads (30%) | catalogued as rs193104548; called by muse, mutect2, varscan2
- SKA1 | c.*949G>A | 3'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as rs959883015; called by muse, mutect2
- SLC6A17 | c.*1778C>G | 3'UTR (SNP) | VAF 24/340 reads (7%) | catalogued as rs536264315; called by muse, mutect2
- SNAP91 | c.*161C>T | 3'UTR (SNP) | VAF 28/400 reads (7%) | catalogued as rs540089169; called by muse, mutect2
- SPACA9 | chr9:132890176 C>T | 3'Flank (SNP) | VAF 9/192 reads (5%) | catalogued as rs1049769295; called by muse, mutect2
- SSH3 | c.67-11T>G | Intron (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- SYT14 | chr1:210162527 A>C | 3'Flank (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- TM9SF2 | chr13:99501430 C>G | 5'Flank (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- TMEM30B | c.*667G>T | 3'UTR (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- TMEM99 | n.444G>A | RNA (SNP) | VAF 65/156 reads (42%) | called by muse, mutect2, varscan2
- TNFAIP1 | c.*1022G>C | 3'UTR (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- VPS37C | c.*1374G>A | 3'UTR (SNP) | VAF 55/157 reads (35%) | called by muse, mutect2, varscan2
- WDR86 | c.163+445C>T | Intron (SNP) | VAF 48/82 reads (59%) | called by muse, mutect2, varscan2
- WIPI2 | c.*2172G>A | 3'UTR (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- ZNF367 | c.*2143T>G | 3'UTR (SNP) | VAF 44/101 reads (44%) | called by muse, mutect2, varscan2
